Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4637, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4637-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (40% CLEAR CELL AND 60% EOSINOPHILIC CELLS) WITH FOCAL

RHABDOID FEATURES, FUHRMAN'S NUCLEAR GRADE 4. (SEE COMMENT)

TUMOR MEASURES 9.0 CM IN THE GREATEST DIMENSION.

METASTATIC RENAL CELL CARCINOMA IN ADRENAL GLAND.

Ureteral, vascular and soft tissue margins of resection, free of tumor.

COMMENT

The tumor is a high grade renal cell carcinoma with focal rhabdoid features. No unequivocal spindle cell sarcomatoid carcinoma component is identified.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND - A nephrectomy specimen (22.0 x 13.0 x 7.0 cm overall), including the kidney (17.0 x 9.0 x 5.0 cm), portion of ureter (2.0 cm in length and 0.3 cm in diameter) and adrenal gland (7.0 x 3.0 x 2.5 cm).

There is a fleshy tan tumor (9.0 x 7.0 x 6.0 cm) in the lower pole abutting the renal capsule but not extending through it. The tumor is grossly 0.4 cm grossly from the inked parenchymal margin. The tumor abuts the renal sinus but grossly does not extend into it. No gross renal vein extension identified. The adrenal gland contains a fleshy tan hemorrhagic tumor measuring 4.0 x 3.0 x 2.5 cm.

A portion of the tumor is submitted for research and electron microscopy.

INK CODE: Black - renal parenchymal margin.

SECTION CODE: A1, ureteral and vascular margin; A2, A3, adrenal with tumor; A4, tumor in relation to renal vein; A5, A6, tumor in relation to renal hilum; A7-A9, tumor in relation to soft tissue margin; A10-A12, additional sections of tumor; A13, uninvolved renal parenchyma.

CLINICAL HISTORY

Renal mass left.

Source: NCI Genomic Data Commons file 91427d38-ce40-4d32-bc00-6965f1cf5159 (TCGA-CJ-4637.69449FD5-F715-4387-B384-4C5421A77E57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).